Gene-level copy-number profile of tumor specimen TCGA-N5-A59E-01A from TCGA case TCGA-N5-A59E, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Myometrium; FIGO stage: Stage IVB; Age at diagnosis: 62.0 years (22,650 days).
Specimen TCGA-N5-A59E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.44ed94c7-549f-4b30-a952-34123516fa62.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A59E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3bdc4ce5-ffb4-4208-be12-19c0521aa108

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,118; copy number 3: 2,718; copy number 4: 23,170; copy number 5: 8,602; copy number 6: 9,789; copy number 7: 4,817; copy number 8: 4,312; copy number 9: 1,909; copy number 10: 212; copy number 11: 467; copy number 12: 903; copy number 13: 438; copy number 14: 146; copy number 15: 163; copy number 16: 2; copy number 17: 1; copy number 20: 27; copy number 23: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A59E-01A-11D-A28Q-01): tumor purity 0.93, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,270 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,858,158–31,987,034, 36 genes, copy number 10: AL445235.1, SDC3, RN7SL371P, PUM1, AL356320.2, AL356320.1, SELENOWP1, AC114495.1, NKAIN1, SNRNP40, AC114495.2, ZCCHC17, AL451070.1, FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1, PEF1, PEF1-AS1, AC114488.2, COL16A1, ADGRB2, MIR4254, AL354919.2, SPOCD1, AL354919.1, AL136115.2, PTP4A2, AL136115.1, AL136115.3.
- chr2:13,710,531–14,400,963, 1 gene, copy number 10 (within-gene range 5–10): LINC00276.
- chr2:14,274,622–57,766,052, 704 genes, copy number 9–11 (broad region; genes not listed).
- chr3:24,687,919–30,010,391, 50 genes, copy number 9–11 (within-gene range 7–11): AC092422.1, RN7SL216P, RNA5SP125, RARB, CFL1P7, RNA5SP126, H3P10, AC093416.1, TOP2B, AC093416.2, MIR4442, CRIP1P2, NGLY1, AC092798.1, TAF9BP1, OXSM, LINC00692, RPEP2, HMGB3P12, VENTXP4, AC099754.1, LRRC3B, NEK10, MICOS10P3, RNU6-342P, AC099535.2, SLC4A7, RPS20P15, AC099535.1, RNU1-96P, AC137675.1, Y_RNA, AC098614.1, AC098614.2, KIAA1143P2, LINC02084, EOMES, LINC01980, LINC01981, LINC01967, CMC1, AZI2, ZCWPW2, AC098650.1, FAM96AP1, AC093142.1, RBMS3, RBMS3-AS3, MESTP4, RPS12P5.
- chr3:89,107,621–90,261,708, 8 genes, copy number 9 (within-gene range 4–9): EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:126,704,240–127,390,670, 12 genes, copy number 13 (within-gene range 5–13): CHCHD6, RCC2P4, AC011199.1, PLXNA1, AC112482.2, C3orf56, Y_RNA, AC112482.1, RNU6-1047P, AC133681.1, PRR20G, LINC02016.
- chr3:166,861,944–194,533,583, 477 genes, copy number 13–23 (broad region; genes not listed).
- chr3:194,827,890–197,299,330, 91 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr4:33,775,498–34,335,351, 5 genes, copy number 9: AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1.
- chr4:90,127,535–91,601,913, 1 gene, copy number 12 (within-gene range 8–12): CCSER1.
- chr4:90,682,996–93,810,157, 18 genes, copy number 12 (within-gene range 3–12): AC093729.1, TMSB4XP8, AC004054.1, AC074124.1, AC110774.1, KRT19P6, AC093810.1, PMPCAP1, AC097520.2, AC097520.1, LNCPRESS2, AC112695.1, GRID2, MTND1P19, AC095059.2, AC095059.1, AC020699.1, AC110800.1.
- chr5:31,595,565–45,895,970, 246 genes, copy number 9 (broad region; genes not listed).
- chr6:167,607–4,602,420, 104 genes, copy number 9 (broad region; genes not listed).
- chr6:46,096,004–46,491,972, 5 genes, copy number 10 (within-gene range 7–10): AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2.
- chr6:78,604,467–78,946,440, 3 genes, copy number 9 (within-gene range 6–9): AL121718.1, AL450327.1, IRAK1BP1.
- chr6:91,390,313–92,388,827, 12 genes, copy number 9: AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1.
- chr6:100,093,311–129,861,547, 386 genes, copy number 9–13 (broad region; genes not listed).
- chr8:41,828,165–43,674,591, 59 genes, copy number 15–20: AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr9:136,940,435–137,168,756, 25 genes, copy number 10: FBXW5, C8G, LCN12, LINC02692, PTGDS, AL807752.7, LCNL1, PAXX, CLIC3, ABCA2, C9orf139, FUT7, AL807752.6, NPDC1, ENTPD2, AL807752.4, AL807752.2, SAPCD2, AL807752.3, UAP1L1, MAN1B1-DT, MAN1B1, SNORD62, DPP7, GRIN1.
- chr12:66,767–34,249,958, 850 genes, copy number 11–14 (broad region; genes not listed).
- chr12:45,014,672–45,610,620, 13 genes, copy number 10: DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6.
- chr12:65,134,688–65,491,430, 6 genes, copy number 12: APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60.
- chr12:67,648,338–67,978,387, 6 genes, copy number 11: DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1.
- chr12:68,001,394–68,036,853, 2 genes, copy number 11: RPL39P28, HNRNPA1P70.
- chr12:68,842,197–72,186,618, 61 genes, copy number 9–13 (within-gene range 8–13) (broad region; genes not listed).
- chr12:72,249,964–72,276,954, 1 gene, copy number 13: TRHDE-AS1.
- chr13:81,114,866–114,337,626, 425 genes, copy number 9 (broad region; genes not listed).
- chr14:23,511,760–24,298,846, 58 genes, copy number 15 (within-gene range 3–15): ZFHX2-AS1, ZFHX2, AL135999.2, THTPA, AP1G2, AL135999.1, JPH4, AL135999.3, DHRS2, AL160237.1, BRD7P1, AL160237.3, RN7SKP205, AL160237.2, AL136419.2, LINC00596, DHRS4-AS1, DHRS4, DHRS4L2, AL136419.1, AL136419.3, DHRS4L1, CARMIL3, CPNE6, NRL, PCK2, DCAF11, AL136295.3, FITM1, PSME1, EMC9, AL136295.2, PSME2, MIR7703, RNF31, AL136295.5, RNA5SP383, IRF9, REC8, IPO4, AL136295.4, AL136295.22, TM9SF1, AL136295.1, AL136295.6, AL136295.7, TSSK4, CHMP4A, AL096870.2, MDP1, NEDD8-MDP1, NEDD8, GMPR2, TINF2, TGM1, RABGGTA, AL096870.12, AL096870.10.
- chr15:90,717,346–90,816,166, 1 gene, copy number 9 (within-gene range 6–9): BLM.
- chr15:90,811,528–91,306,321, 24 genes, copy number 9: AC124248.2, AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3, UNC45A, RCCD1-AS1, RCCD1, PRC1, AC068831.6, PRC1-AS1, Y_RNA, VPS33B, VPS33B-DT, AC068831.5, AC068831.1, AC068831.4, AC068831.2, AC127520.1, SV2B, AC123784.1.
- chr16:30,569,346–34,163,110, 228 genes, copy number 11–14 (broad region; genes not listed).
- chr16:46,469,341–46,973,674, 19 genes, copy number 9 (within-gene range 7–9): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2.
- chr16:47,218,026–47,263,500, 2 genes, copy number 9: AC007494.3, AC007494.1.
- chr18:33,851,100–37,992,413, 60 genes, copy number 9 (within-gene range 6–9): NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1.
- chr18:48,475,487–49,492,523, 30 genes, copy number 9: RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B.
- chr18:77,863,464–78,140,887, 5 genes, copy number 9: RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1.
- chr19:29,083,094–30,957,192, 35 genes, copy number 9: AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr20:87,250–1,118,467, 28 genes, copy number 9 (within-gene range 8–9): DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1.
- chr20:12,243,308–16,053,197, 36 genes, copy number 10 (within-gene range 8–10): AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.
- chr20:30,377,372–34,540,748, 135 genes, copy number 9–12 (within-gene range 7–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
